Somatic mutation profile of tumor specimen TCGA-VQ-A8PK-01A (aliquot TCGA-VQ-A8PK-01A-12D-A410-08) from TCGA case TCGA-VQ-A8PK, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.6 years (21,419 days).
Specimen TCGA-VQ-A8PK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8efaffa-1683-4336-ab9d-0c7e56977793.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PK-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PK-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae83691c-42f1-4400-ae78-4f840119627c

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 24, Frame Shift Del 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330865474, CM151471, COSV52674699, COSV52714188, COSV52767322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB7 | c.389C>T p.P130L (on ENST00000373394 / NM_001271696.3; = p.P131L on NM_004299.6) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV99504785, COSV99504861; called by muse, mutect2, varscan2
- ABCC9 | c.542T>C p.M181T | Missense Mutation (SNP) | VAF 123/513 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV99687013; called by muse, mutect2, varscan2
- ADCY6 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754255254, COSV57168237; called by muse, mutect2, varscan2
- ARHGAP10 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100331719; called by muse, mutect2, varscan2
- ASTN2 | c.1798A>C p.S600R (on ENST00000313400 / NM_001365069.1; = p.S549R on NM_014010.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV100530158; called by muse, mutect2, varscan2
- BEND4 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV101549796; called by muse, mutect2, varscan2
- BPTF | c.8196G>C p.Q2732H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100075931; called by muse, mutect2, varscan2
- CDH9 | c.1597C>T p.L533F | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.222); catalogued as COSV99151638; called by muse, mutect2
- CMYA5 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV71408969; called by muse, mutect2, varscan2
- CNTN6 | c.2594A>C p.N865T | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV100611770; called by muse, mutect2, varscan2
- CNTNAP4 | c.1286A>C p.K429T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV56668876, COSV56704353; called by muse, mutect2, varscan2
- COX4I2 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064277; called by muse, mutect2, varscan2
- CPNE6 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1419002727, COSV99393720; called by muse, mutect2, varscan2
- CSMD1 | c.1694T>G p.V565G (on ENST00000520002; = p.V564G on NM_033225.6) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100153146; called by muse, mutect2
- CSMD3 | c.5834A>C p.K1945T (on ENST00000297405 / NM_001363185.1; = p.K1841T on NM_052900.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99846300; called by muse, mutect2, varscan2
- CTLA4 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55592424; called by muse, mutect2, varscan2
- DENND5B | c.3557G>T p.C1186F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100172096; called by muse, mutect2
- DFFA | c.402T>G p.D134E | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100986686; called by muse, mutect2, varscan2
- DGKH | c.1922A>T p.D641V | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1429279444, COSV54936790, COSV99819499; called by muse, mutect2, varscan2
- DIDO1 | c.6092G>A p.S2031N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.497); catalogued as COSV99826968; called by muse, mutect2
- DNAH9 | c.7280A>G p.K2427R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as rs779029181, COSV52332249, COSV52347707, COSV99307837; called by muse, mutect2, varscan2
- DNAJB1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748841793, COSV99584251; called by muse, mutect2, varscan2
- DOCK6 | c.5324C>T p.S1775L | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs771559139, COSV99626565; called by muse, mutect2, varscan2
- DOK2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs539220753, COSV52390033; called by muse, mutect2
- EDNRB | c.1316T>G p.L439R (on ENST00000377211 / NM_001201397.1; = p.L349R on NM_000115.5) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); catalogued as COSV100527031; called by muse, mutect2, varscan2
- EDNRB | c.794A>C p.K265T (on ENST00000377211 / NM_001201397.1; = p.K175T on NM_000115.5) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100527032; called by muse, mutect2, varscan2
- EHMT2 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs201104297, COSV100977241; called by muse, mutect2, varscan2
- ELN | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1554670449, COSV99332056; called by muse, mutect2, varscan2
- ERBB4 | c.456C>G p.N152K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53601282, COSV99631701; called by muse, mutect2, varscan2
- F13A1 | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341933, COSV99343830; called by muse, mutect2, varscan2
- FAM135B | c.2809T>G p.L937V | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV99427067; called by muse, mutect2, varscan2
- FGD4 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1025203055, COSV56781619; called by muse, mutect2, varscan2
- FGF13 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59544307; called by muse, mutect2, varscan2
- GRID2 | c.883A>C p.S295R | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.604); catalogued as COSV56178862; called by muse, mutect2, varscan2
- GRM3 | c.1073A>C p.K358T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.743); catalogued as COSV64472253; called by muse, mutect2, varscan2
- IQGAP2 | c.1410G>C p.L470F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV56971911; called by muse, mutect2
- MEIS1 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99715634, COSV99715741; called by muse, mutect2
- MYNN | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as rs758293221, COSV62991547; called by muse, mutect2, varscan2
- MYO18B | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as rs1161485357, COSV100124994; called by muse, mutect2, varscan2
- NRK | c.3352T>G p.S1118A | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV54608185, COSV99689056; called by muse, mutect2, varscan2
- OR10AG1 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100400136, COSV100400189; called by muse, mutect2, varscan2
- OR2T10 | c.674T>A p.I225N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100393806; called by muse, mutect2, varscan2
- OR2T2 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749616270, COSV61617945; called by mutect2, varscan2
- OR2T33 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs138653777; called by muse, mutect2, varscan2
- OR4N2 | c.63A>C p.Q21H | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100269961, COSV60053544; called by muse, mutect2
- OR51D1 | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.595); catalogued as COSV100712430; called by muse, mutect2, varscan2
- PCARE | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.66); catalogued as COSV59053744; called by muse, mutect2, varscan2
- PCDH15 | c.5242C>A p.P1748T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV57374312; called by muse, mutect2, varscan2
- PIK3CG | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as rs1383854511, COSV63246020; called by muse, mutect2, varscan2
- PRR23B | c.756A>C p.E252D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.17); catalogued as COSV100271884, COSV100272206; called by muse, mutect2, varscan2
- PTPRJ | c.2896T>G p.L966V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101395748; called by muse, mutect2, varscan2
- SEPTIN7 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100621890; called by muse, mutect2, varscan2
- SLC25A12 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99785380; called by muse, mutect2, varscan2
- SYNE2 | c.4190C>A p.T1397N | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs760136466, COSV100648414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAS2R10 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99555632; called by muse, mutect2, varscan2
- TEK | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101193549; called by muse, mutect2, varscan2
- TFAP2D | c.826T>G p.L276V | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99147357, COSV99148083; called by muse, mutect2
- TLE4 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54636353; called by muse, mutect2, varscan2
- TMEM200A | c.1117T>G p.L373V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as COSV51657334, COSV99759999; called by muse, mutect2, varscan2
- TMEM200C | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101274865; called by muse, mutect2, varscan2
- TPTE2 | c.1524T>G p.I508M (on ENST00000400230 / NM_199254.2; = p.I431M on NM_130785.3) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs780874714, COSV55027931; called by muse, mutect2, varscan2
- TTN | c.43657A>G p.R14553G (on ENST00000591111; = p.R7129G on NM_003319.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | PolyPhen benign (0.033); catalogued as COSV100627835; called by muse, mutect2, varscan2
- TUBA3C | c.598T>A p.C200S | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101262836; called by muse, mutect2, varscan2
- VAT1L | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284657019, COSV56822238; called by muse, mutect2
- WWC3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as COSV101081737; called by muse, mutect2, varscan2
- ZBTB38 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357720132, COSV58540176; called by muse, mutect2, varscan2
- ZGPAT | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs1375440517, COSV100203290; called by muse, mutect2, varscan2
- ZNF221 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV52108036, COSV99240926; called by muse, mutect2, varscan2
- ZNF347 | c.2354G>A p.R785K | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100498413; called by muse, mutect2
- ZNF501 | c.665A>T p.E222V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as COSV101247152; called by muse, mutect2, varscan2
- ZNF682 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.491); catalogued as rs1568538033, COSV100653350; called by muse, mutect2, varscan2
- ZNF695 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100377699, COSV60584731, COSV60587857; called by muse, mutect2, varscan2
- HCN1 | c.348_360del p.S116Rfs*28 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- ST3GAL2 | c.851_860del p.L284Pfs*8 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by pindel, varscan2
- C11orf87 | c.84C>T p.S28= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59356486, COSV99046618; called by muse, varscan2
- CEP85 | c.1491G>A p.Q497= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99432919; called by muse, mutect2, varscan2
- DCC | c.1383T>C p.T461= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100502668; called by muse, mutect2, varscan2
- DCLK1 | c.201A>T p.R67= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99712838; called by muse, mutect2, varscan2
- DGKK | c.654G>A p.L218= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV101053195; called by muse, mutect2, varscan2
- EIF2AK1 | c.234C>T p.H78= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs140066459, COSV99552186; called by muse, mutect2, varscan2
- ELN | c.510C>T p.P170= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99333078; called by muse, mutect2, varscan2
- F9 | c.558T>G p.T186= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV54380351, COSV54382823, COSV99496388; called by mutect2, varscan2
- FRMD4A | c.2007C>T p.S669= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV100662391; called by muse, mutect2, varscan2
- IGKV1-12 | c.45C>A p.L15= | Silent (SNP) | VAF 45/345 reads (13%) | called by muse, mutect2, varscan2
- IGSF22 | c.1224A>G p.Q408= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100080319; called by muse, mutect2, varscan2
- NRG1 | c.1155T>C p.T385= (on ENST00000405005 / NM_013964.5; = p.T390= on NM_013956.5) | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1348380163, COSV55174855, COSV99829412; called by muse, mutect2
- PLA2G4D | c.844C>T p.L282= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as rs763109343, COSV99300012; called by muse, mutect2, varscan2
- RRH | c.354C>T p.V118= | Silent (SNP) | VAF 72/103 reads (70%) | catalogued as rs373432160; called by muse, mutect2, varscan2
- SWT1 | c.1191G>C p.L397= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100833511; called by muse, mutect2, varscan2
- SYT10 | c.897T>G p.T299= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99951934; called by muse, mutect2, varscan2
- TAF3 | c.1977A>G p.K659= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100720460; called by muse, mutect2, varscan2
- TMF1 | c.3240C>T p.Y1080= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV101275462; called by muse, mutect2, varscan2
- USP51 | c.918A>G p.E306= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV101540694; called by muse, mutect2, varscan2
- WNT10A | c.780G>A p.R260= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1347420983, COSV99297563; called by muse, mutect2
- ZDBF2 | c.5136T>C p.F1712= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100985478; called by muse, mutect2, varscan2
- ZEB1 | c.2991G>A p.E997= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100314975, COSV58046786; called by muse, mutect2, varscan2
- ZIM2 | c.1083T>C p.C361= | Silent (SNP) | VAF 58/84 reads (69%) | catalogued as rs201319550, COSV99690248; called by muse, mutect2, varscan2
- ZNF512 | c.273C>T p.V91= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs369976994, COSV100820982; called by muse, mutect2, varscan2
- C7orf66 | n.379T>G | RNA (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
